Somatic mutation profile of tumor specimen TCGA-HU-A4GT-01A (aliquot TCGA-HU-A4GT-01A-21D-A25D-08) from TCGA case TCGA-HU-A4GT, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 71.8 years (26,231 days).
Specimen TCGA-HU-A4GT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26518c53-e6ea-4c6a-bd6c-3fd9788982d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4GT-10A (Blood Derived Normal), aliquot TCGA-HU-A4GT-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2639f6d2-5ac8-4493-b63e-63ba710a48c6

The open-access MAF lists 1,695 somatic variants for this specimen: 1,293 protein-altering or splice-affecting, 366 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 845, Silent 366, Frame Shift Del 268, Frame Shift Ins 92, Nonsense Mutation 33, Splice Site 27, In Frame Del 14, Intron 13, 5'UTR 9, Splice Region 9, RNA 7, 3'UTR 4.

Variants (750 of 1,695; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.3034_3036del p.K1012del | In Frame Del (DEL) | VAF 54/145 reads (37%) | hotspot (GDC flag); catalogued as rs761762028; called by pindel, varscan2
- ATM | c.640del p.S214Pfs*16 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | catalogued as rs786204543; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CHD2 | c.3734del p.K1245Nfs*4 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs752940775; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- COL12A1 | c.7001T>C p.I2334T | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs796052093, CM144039, COSV59409694; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KAT14 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs771882905, CM1512493, COSV66609497; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LRP5 | c.1142A>G p.D381G | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs886040977, COSV53724649; ClinVar: likely pathogenic; called by muse, mutect2
- MEN1 | c.1561dup p.R521Pfs*15 | Frame Shift Ins (INS) | VAF 7/40 reads (18%) | catalogued as rs767319284; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs397514641, CM000774, COSV62197492; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 28/60 reads (47%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 19/76 reads (25%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PROP1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769171020, CM024247, COSV57644943; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLCO2A1 | c.830del p.F277Sfs*8 | Frame Shift Del (DEL) | VAF 40/96 reads (42%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- AADACL3 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as rs748929112, COSV100206829, COSV60198875; called by muse, mutect2, varscan2
- AANAT | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs765693283, COSV51686213; called by muse, mutect2, varscan2
- ABCA8 | c.4478T>C p.L1493P | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52213695; called by muse, mutect2, varscan2
- ABCC10 | c.1874A>G p.K625R (on ENST00000372530 / NM_001198934.2; = p.K597R on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV55094635; called by muse, mutect2, varscan2
- ABCC8 | c.1487T>C p.L496P | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56858679; called by muse, mutect2, varscan2
- ABHD8 | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as COSV56046538, COSV99917171; called by muse, mutect2, varscan2
- ABTB1 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as rs1439332207, COSV51743144; called by muse, mutect2, varscan2
- AC098582.1 | c.1431G>T p.M477I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52025699; called by muse, mutect2, varscan2
- ACAN | c.7594G>A p.G2532R (on ENST00000560601 / NM_001369268.1; = p.G2494R on NM_013227.3) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746885216, COSV61370597; called by muse, mutect2, varscan2
- ACHE | c.764G>T p.R255M | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53822056; called by muse, mutect2, varscan2
- ACOT8 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs749132839, COSV54170120; called by muse, mutect2, varscan2
- ACTL7A | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs139001396; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 48/68 reads (71%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM30 | c.1137del p.F379Lfs*11 | Frame Shift Del (DEL) | VAF 53/152 reads (35%) | catalogued as rs1468166203, COSV65560585; called by mutect2, pindel, varscan2
- ADAMTS14 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs1022120582, COSV64607076; called by muse, mutect2, varscan2
- ADAMTS7 | c.2446G>A p.D816N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs3825828, COSV66306973, COSV66309919; called by muse, mutect2, varscan2
- ADAMTSL3 | c.971C>T p.T324I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as COSV54472892; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3687G>T p.K1229N | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54472902; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2483del p.P828Rfs*120 | Frame Shift Del (DEL) | VAF 65/150 reads (43%) | catalogued as rs771762024; called by mutect2, pindel, varscan2
- ADCY10 | c.2191T>G p.C731G | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.3); catalogued as COSV63245560; called by muse, mutect2, varscan2
- ADCY10 | c.1126G>T p.V376F | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV63245565; called by muse, mutect2, varscan2
- ADCY6 | c.1619C>A p.A540E | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV57170984; called by muse, mutect2, varscan2
- ADCY8 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs905326364, COSV53930895; called by muse, mutect2, varscan2
- ADD2 | c.1555C>T p.L519F | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV52473061; called by muse, mutect2
- ADGRB1 | c.3925C>A p.L1309I | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); catalogued as COSV60103960; called by muse, mutect2, varscan2
- ADGRL1 | c.1579C>A p.P527T (on ENST00000340736 / NM_001008701.3; = p.P522T on NM_014921.5) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61566930; called by muse, mutect2, varscan2
- ADGRV1 | c.14404C>T p.R4802* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as rs1236715896, CM0911268, COSV67978996; called by muse, mutect2
- ADGRV1 | c.15158A>G p.E5053G | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV67996636; called by muse, mutect2, varscan2
- ADNP2 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.062); catalogued as rs199728633; called by muse, mutect2, varscan2
- ADPRHL1 | c.347T>G p.L116R | Missense Mutation (SNP) | VAF 62/369 reads (17%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.986); catalogued as COSV62911056; called by muse, mutect2, varscan2
- AFF2 | c.3034G>A p.A1012T | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.659); catalogued as rs782756910, COSV53987870; called by muse, mutect2, varscan2
- AGAP1 | c.1366A>G p.I456V | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58340698; called by muse, mutect2, varscan2
- AGTR2 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782155285, COSV64156404; called by muse, mutect2, varscan2
- AHDC1 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs779580540, COSV55942831; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKR7A2 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1200816234, COSV52517024; called by mutect2, varscan2
- AKR7L | c.868A>G p.S290G | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV101334286; called by muse, mutect2, varscan2
- ALAS2 | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58193713; called by muse, mutect2, varscan2
- ALG1 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs750216032, COSV52159703; called by muse, mutect2, varscan2
- ALOX12 | c.1642C>T p.L548= | Splice Region (SNP) | VAF 22/62 reads (35%) | catalogued as COSV52352688; called by muse, mutect2, varscan2
- ALOX15 | c.1247A>G p.Q416R | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV53401150; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 71/225 reads (32%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- AMPD3 | c.1850T>C p.V617A (on ENST00000396553 / NM_001025389.2; = p.V626A on NM_000480.3) | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.604); catalogued as COSV67332824; called by muse, mutect2
- ANK1 | c.3375G>T p.Q1125H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV55897755; called by muse, mutect2, varscan2
- ANK1 | c.2834C>T p.A945V | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs373287341; called by muse, mutect2, varscan2
- ANK1 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs561437854, COSV55897779; called by muse, mutect2, varscan2
- ANK1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV55897790; called by muse, mutect2, varscan2
- ANKLE1 | c.1202G>T p.R401M (on ENST00000394458; = p.R347M on NM_152363.6) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV63921707; called by muse, mutect2, varscan2
- ANKRD12 | c.930_932dup p.D310dup | In Frame Ins (INS) | VAF 20/80 reads (25%) | catalogued as rs1042677794; called by mutect2, varscan2
- ANKRD13B | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.469); catalogued as COSV61472162; called by muse, mutect2, varscan2
- ANKRD17 | c.6365C>A p.P2122H | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.343); catalogued as COSV58228776; called by muse, mutect2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD54 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375913161; called by muse, mutect2, varscan2
- ANPEP | c.2664T>A p.F888L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV55595702; called by muse, varscan2
- AP1B1 | c.85A>G p.K29E | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); catalogued as COSV100434611; called by muse, mutect2
- AP3M2 | c.563A>G p.D188G | Missense Mutation (SNP) | VAF 121/278 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51530946; called by muse, mutect2, varscan2
- APBA2 | c.2095C>T p.R699C | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755413618, COSV68792602; called by muse, mutect2, varscan2
- APBB3 | c.737T>G p.L246R (on ENST00000357560 / NM_133173.2; = p.L253R on NM_006051.3) | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV60054669; called by muse, mutect2, varscan2
- ARAP2 | c.4130T>C p.F1377S | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58293427; called by muse, mutect2, varscan2
- ARCN1 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs367554879; called by muse, mutect2
- ARFGEF1 | c.4655dup p.P1553Tfs*7 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as rs774148781; called by mutect2, varscan2
- ARHGAP39 | c.994del p.V332Cfs*52 | Frame Shift Del (DEL) | VAF 22/117 reads (19%) | catalogued as COSV52775951; called by mutect2, pindel, varscan2
- ARHGEF10 | c.3961C>T p.R1321C (on ENST00000398564; = p.R1296C on NM_014629.4) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs747279075, COSV50683984; called by muse, mutect2, varscan2
- ARHGEF12 | c.2764C>A p.R922S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63102620, COSV63107720; called by muse, mutect2, varscan2
- ARIH2 | c.920A>G p.N307S | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as COSV62706582; called by muse, mutect2
- ARL14EP | c.266del p.N89Ifs*4 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs1247324796; called by mutect2, varscan2
- ARL6IP6 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs773818874, COSV58444728; called by muse, mutect2, varscan2
- ARNT2 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57585995; called by muse, mutect2, varscan2
- ARSK | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.806); catalogued as rs770798168, COSV66170589; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASB10 | c.859G>A p.A287T (on ENST00000420175 / NM_001142459.2; = p.A272T on NM_080871.4) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.582); catalogued as rs1300802233, COSV51996694, COSV52001143; called by muse, mutect2, varscan2
- ASB6 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as COSV52965446, COSV52965572; called by muse, mutect2, varscan2
- ASH1L | c.1243G>T p.G415C | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as COSV64214617; called by muse, mutect2, varscan2
- ASIP | c.265del p.L89Yfs*69 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs767121271; called by mutect2, pindel, varscan2
- ASL | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1562742560, COSV59189626; called by muse, mutect2, varscan2
- ASPG | c.1412T>C p.L471P | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71934192; called by muse, mutect2, varscan2
- ASPSCR1 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs781445169, COSV60730953, COSV60731485; called by mutect2, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | catalogued as rs771531141; called by mutect2, varscan2
- ATG9A | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.132); catalogued as COSV63446985; called by muse, mutect2
- ATP11A | c.2491A>G p.S831G | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV52126155; called by muse, mutect2, varscan2
- ATP13A1 | c.2974G>T p.A992S | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV52291919; called by muse, mutect2, varscan2
- ATP13A1 | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV52291941; called by muse, mutect2, varscan2
- ATP13A2 | c.2015A>G p.D672G | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs981910553, COSV58704366; called by muse, mutect2
- ATP13A3 | c.3079del p.W1027Gfs*31 | Frame Shift Del (DEL) | VAF 24/44 reads (55%) | catalogued as rs746602775; called by mutect2, varscan2
- ATP1A1 | c.2323T>C p.S775P | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55194665; called by muse, mutect2, varscan2
- ATP2B2 | c.947C>T p.A316V (on ENST00000352432; = p.A327V on NM_001001331.4) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.312); catalogued as rs149708084, COSV59508064; called by muse, mutect2, varscan2
- ATP4A | c.2855G>A p.R952H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1423443034, COSV52872418; called by muse, mutect2, varscan2
- ATP7A | c.1594T>C p.Y532H | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58455365; called by muse, mutect2
- ATP8B1 | c.1409G>A p.C470Y | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV52180918; called by muse, mutect2, varscan2
- ATP8B4 | c.3121A>G p.S1041G | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV52725777; called by muse, mutect2, varscan2
- ATR | c.3974G>A p.S1325N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as COSV63393474; called by muse, mutect2
- ATXN2L | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.984); catalogued as COSV57379959; called by muse, mutect2, varscan2
- ATXN2L | c.3004dup p.Q1002Pfs*29 | Frame Shift Ins (INS) | VAF 30/105 reads (29%) | catalogued as rs771612620; called by mutect2, varscan2
- AURKC | c.139C>T p.R47C (on ENST00000302804 / NM_001015878.2; = p.R13C on NM_003160.3) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs766182833, COSV57136984; called by muse, mutect2, varscan2
- AVL9 | c.245del p.N82Mfs*21 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as COSV100594887; called by mutect2, pindel
- B3GLCT | c.848G>A p.R283K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58459283; called by muse, mutect2, varscan2
- B3GNT6 | c.1010C>A p.P337H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781984195, COSV62827854; called by muse, mutect2
- BAG6 | c.2759T>C p.L920P (on ENST00000676571; = p.L873P on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52995823; called by muse, mutect2
- BBX | c.1429C>T p.Q477* | Nonsense Mutation (SNP) | VAF 36/106 reads (34%) | catalogued as COSV57896195; called by muse, mutect2, varscan2
- BCL9L | c.3646T>C p.C1216R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV52689799; called by muse, mutect2, varscan2
- BCOR | c.679T>C p.Y227H | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV60720201; called by muse, mutect2, varscan2
- BEX5 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.025); catalogued as rs1280250635, COSV61329055, COSV61329100; called by muse, varscan2
- BICC1 | c.2414A>T p.E805V | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54067442; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs755506199; called by mutect2, varscan2
- BLMH | c.1216G>T p.G406C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55587252; called by muse, varscan2
- BLVRA | c.632+2T>C p.X211_splice | Splice Site (SNP) | VAF 19/102 reads (19%) | catalogued as COSV55516704; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BORCS5 | c.523A>C p.S175R | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV53805353; called by muse, mutect2, varscan2
- BRAT1 | c.2300A>G p.Q767R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV61397547; called by muse, mutect2
- BRCA2 | c.10024G>A p.E3342K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs28897761, COSV66337145; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- BRSK2 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1564867655, COSV57549975; called by muse, mutect2, varscan2
- BSN | c.5507A>T p.E1836V | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as COSV56529219; called by muse, mutect2, varscan2
- BTN3A1 | c.1227del p.I409Mfs*16 | Frame Shift Del (DEL) | VAF 50/140 reads (36%) | catalogued as COSV99175662; called by pindel, varscan2
- BUD23 | c.642+2T>C p.X214_splice | Splice Site (SNP) | VAF 38/171 reads (22%) | catalogued as COSV56096554; called by muse, mutect2, varscan2
- BZW1 | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV63350465; called by muse, mutect2, varscan2
- C11orf45 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.369); catalogued as rs1007967010, COSV57971818; called by muse, mutect2, varscan2
- C18orf54 | c.529A>G p.M177V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1442226005, COSV55619747; called by muse, mutect2
- C1GALT1C1 | c.215T>C p.I72T | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as COSV58973869; called by muse, mutect2, varscan2
- C1QA | c.668del p.K223Rfs*59 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | catalogued as rs1433567552; called by mutect2, pindel, varscan2
- C1QTNF4 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV56784672; called by muse, mutect2, varscan2
- C5orf24 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); catalogued as COSV57543462; called by muse, mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, pindel, varscan2
- CA12 | c.1002del p.G335Vfs*108 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | catalogued as rs765638256; called by mutect2, pindel, varscan2
- CABLES2 | c.1249A>G p.K417E | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1569014434, COSV54158792; called by muse, mutect2, varscan2
- CACNA1B | c.3871C>A p.L1291I | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53151838; called by muse, mutect2
- CACNA1C | c.5005A>G p.I1669V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as rs1275157467, COSV59779550; called by muse, mutect2, varscan2
- CACNA1E | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.086); catalogued as rs776757923, COSV62406537; called by muse, mutect2, varscan2
- CALB1 | c.284A>G p.Q95R | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV55369883; called by muse, mutect2, varscan2
- CALD1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | catalogued as COSV62655125; called by muse, mutect2
- CAMK1D | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs763584729, COSV66607331; called by muse, mutect2, varscan2
- CAMK2G | c.1072G>A p.A358T (on ENST00000423381 / NM_001367518.1; = p.A368T on NM_172170.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.049); catalogued as rs371217848; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMSAP3 | c.2336G>A p.R779H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as COSV50373132; called by muse, mutect2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | catalogued as rs745547658; called by mutect2, varscan2
- CANX | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 80/234 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV56002528; called by muse, mutect2, varscan2
- CAPRIN2 | c.1708T>C p.W570R | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99195513; called by muse, mutect2, varscan2
- CARMIL3 | c.3466G>A p.G1156S | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs149692862; called by muse, mutect2, varscan2
- CASK | c.2519A>G p.Q840R (on ENST00000378163 / NM_001367721.1; = p.Q835R on NM_003688.3) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs1197990262, COSV59376507; called by muse, mutect2, varscan2
- CASKIN1 | c.276G>T p.Q92H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV58877658; called by muse, mutect2, varscan2
- CATSPER1 | c.2276A>C p.Q759P | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV56413937; called by muse, mutect2, varscan2
- CBX4 | c.690dup p.N231Qfs*81 | Frame Shift Ins (INS) | VAF 30/92 reads (33%) | catalogued as rs772839792; called by mutect2, varscan2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 60/201 reads (30%) | catalogued as rs756536005; called by mutect2, pindel, varscan2
- CCDC146 | c.1814A>G p.Q605R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV53555433; called by muse, mutect2, varscan2
- CCDC184 | c.328A>G p.S110G | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.022); catalogued as rs146722647, COSV57252593; called by muse, mutect2, varscan2
- CCDC63 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 63/71 reads (89%) | SIFT tolerated (0.37); PolyPhen benign (0.138); catalogued as rs148044780; called by muse, mutect2, varscan2
- CCDC9B | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV66875430; called by muse, mutect2, varscan2
- CD101 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs34397029; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 39/124 reads (31%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD69 | c.284A>G p.K95R | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV57303924; called by muse, mutect2, varscan2
- CD93 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.029); catalogued as COSV55663893, COSV55669272; called by muse, mutect2, varscan2
- CDAN1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs772703075, COSV51182868; called by muse, mutect2, varscan2
- CDH12 | c.2352A>C p.E784D | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.245); catalogued as COSV66394408; called by muse, mutect2, varscan2
- CDH13 | c.1369G>A p.G457S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.7); PolyPhen probably damaging (1); catalogued as rs372445890, COSV51788416, COSV51865214; called by muse, mutect2, varscan2
- CDH2 | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370333144; called by muse, mutect2, varscan2
- CDH6 | c.1926del p.E643Sfs*3 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | catalogued as rs1561075636; called by mutect2, pindel, varscan2
- CDK11B | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV58341610; called by muse, mutect2, varscan2
- CDK15 | c.1033C>T p.R345* (on ENST00000652192 / NM_001366386.2; = p.R294* on NM_139158.2) | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as rs370382391; called by muse, mutect2, varscan2
- CEACAM5 | c.1888A>G p.N630D | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as COSV55750396; called by muse, mutect2
- CEL | c.2248A>G p.M750V (on ENST00000673714; = p.M747V on NM_001807.6) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV60829967; called by muse, mutect2, varscan2
- CELF2 | c.1244G>T p.S415I (on ENST00000416382 / NM_001025077.3; = p.S428I on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV59983748; called by muse, mutect2, varscan2
- CELSR2 | c.2681T>C p.V894A | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54780284; called by muse, mutect2, varscan2
- CELSR3 | c.5258G>A p.G1753D | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51168426; called by muse, mutect2
- CEP192 | c.4257+2T>C p.X1419_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV58071460; called by muse, mutect2, varscan2
- CEP290 | c.4514T>C p.L1505P | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58357105; called by muse, mutect2
- CEP72 | c.1058G>A p.C353Y | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs1463689147, COSV53789989; called by muse, mutect2, varscan2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs747835123, COSV61504174; called by mutect2, pindel, varscan2
- CFAP251 | c.2084G>A p.S695N | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV56616537; called by muse, mutect2, varscan2
- CFAP36 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59119536; called by muse, mutect2, varscan2
- CFAP65 | c.416A>G p.K139R (on ENST00000341552 / NM_194302.4; = p.K74R on NM_152389.4) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV55392126; called by muse, mutect2
- CFH | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.125); catalogued as COSV66414325; called by muse, varscan2
- CHD4 | c.3040G>A p.V1014M (on ENST00000357008 / NM_001363606.2; = p.V1027M on NM_001273.5) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.66); catalogued as COSV58912148; called by muse, mutect2, varscan2
- CHD6 | c.3419A>G p.Y1140C | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58562968; called by muse, mutect2, varscan2
- CHERP | c.809A>C p.N270T | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52228072; called by muse, mutect2
- CHPF2 | c.1941dup p.S648Lfs*6 | Frame Shift Ins (INS) | VAF 11/30 reads (37%) | catalogued as rs746469175; called by mutect2, varscan2
- CHRAC1 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55270465; called by muse, mutect2, varscan2
- CIC | c.3347dup p.S1117Kfs*34 | Frame Shift Ins (INS) | VAF 22/85 reads (26%) | catalogued as rs761345552; called by mutect2, varscan2
- CIZ1 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV52973309; called by muse, mutect2, varscan2
- CLDN6 | c.511T>C p.S171P | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV58510850; called by muse, mutect2, varscan2
- CMYA5 | c.3666G>T p.Q1222H | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV71406126; called by muse, mutect2, varscan2
- CNDP1 | c.517T>C p.W173R | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs758303238, COSV62595588; called by muse, mutect2, varscan2
- CNDP2 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs540790918, COSV60841893; called by muse, mutect2, varscan2
- CNN3 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.807); catalogued as COSV54734417; called by muse, mutect2, varscan2
- CNTNAP1 | c.1758G>T p.E586D | Missense Mutation (SNP) | VAF 88/205 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV52854854; called by muse, mutect2, varscan2
- CNTROB | c.2699dup p.V901Sfs*25 | Frame Shift Ins (INS) | VAF 15/58 reads (26%) | catalogued as rs35508310; called by mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | catalogued as rs374805044; called by mutect2, varscan2
- COCH | c.1076T>A p.V359D (on ENST00000216361 / NM_001347720.1; = p.V294D on NM_004086.3) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV53553315; called by muse, mutect2, varscan2
- COL12A1 | c.4966C>T p.P1656S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs1233075420, COSV59409704; called by muse, mutect2, varscan2
- COL1A2 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51967244, COSV99799819; called by muse, mutect2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 11/28 reads (39%) | catalogued as rs760493024; called by mutect2, varscan2
- COL25A1 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 33/123 reads (27%) | catalogued as rs759316372, COSV67654943; called by muse, mutect2, varscan2
- COLEC12 | c.277T>A p.L93I | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV68374431; called by muse, mutect2, varscan2
- COQ8B | c.105A>T p.G35= | Splice Region (SNP) | VAF 12/123 reads (10%) | catalogued as COSV54577801; called by muse, mutect2
- CPD | c.4105G>T p.D1369Y | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV56716810; called by muse, mutect2, varscan2
- CPO | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs144914072; called by muse, mutect2, varscan2
- CPSF1 | c.3860-2A>G p.X1287_splice | Splice Site (SNP) | VAF 6/82 reads (7%) | catalogued as COSV58235848; called by muse, mutect2
- CRELD2 | c.133A>G p.M45V | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV58208645; called by muse, mutect2, varscan2
- CRHR2 | c.917G>T p.R306M | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59268273; called by muse, mutect2
- CRISPLD1 | c.196T>A p.L66M | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51553608; called by muse, mutect2, varscan2
- CRYBG3 | c.7589A>G p.E2530G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV51716785; called by muse, mutect2, varscan2
- CSAD | c.1007T>G p.L336R (on ENST00000444623 / NM_001244705.2; = p.L363R on NM_015989.5) | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57245262; called by muse, mutect2
- CSAG3 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs1348141659; called by mutect2, varscan2
- CSMD1 | c.8152G>A p.V2718M (on ENST00000520002; = p.V2717M on NM_033225.6) | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs779488083, COSV59370438; called by muse, mutect2, varscan2
- CSMD1 | c.5428C>T p.R1810* (on ENST00000520002; = p.R1809* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV59362949; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSMD3 | c.9050T>C p.V3017A (on ENST00000297405 / NM_001363185.1; = p.V2848A on NM_052900.3) | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV52338096; called by muse, mutect2, varscan2
- CSMD3 | c.837T>G p.I279M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52338128; called by muse, mutect2, varscan2
- CUL9 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); catalogued as rs750831849, COSV52735753; called by muse, mutect2, varscan2
- CWF19L2 | c.977del p.N326Ifs*19 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as COSV56519025; called by mutect2, pindel, varscan2
- CYB5R3 | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61546842; called by muse, mutect2
- CYP17A1 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64005179; called by muse, mutect2
- CYP17A1 | c.177dup p.Y60Ifs*29 | Frame Shift Ins (INS) | VAF 22/118 reads (19%) | catalogued as rs1402132413; called by mutect2, pindel, varscan2
- CYP4B1 | c.1490G>A p.G497D | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751026514, COSV54726641; called by muse, mutect2, varscan2
- DAG1 | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1352857133, COSV58187712; called by muse, mutect2
- DDB1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as rs1205322944, COSV57106308; called by muse, mutect2, varscan2
- DDX10 | c.238del p.T80Hfs*2 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs1176416201; called by mutect2, pindel, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX42 | c.2792G>A p.R931H | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as rs1431668978, COSV63791577; called by muse, mutect2, varscan2
- DEFB113 | c.97A>G p.R33G | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV59038633; called by muse, mutect2
- DENND10 | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs945230812, COSV63858312; called by muse, mutect2, varscan2
- DENND2A | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745399243, COSV52059516; called by muse, mutect2, varscan2
- DEPP1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); catalogued as COSV53575256; called by muse, mutect2, varscan2
- DGAT1 | c.370T>A p.F124I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV100184050; called by muse, mutect2
- DGKH | c.732C>T p.V244= | Splice Region (SNP) | VAF 27/47 reads (57%) | catalogued as rs1260512603, COSV54933496; called by muse, mutect2, varscan2
- DGKH | c.2381A>G p.H794R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54943273; called by muse, mutect2
- DGKK | c.3790C>A p.L1264I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV65708592; called by muse, mutect2, varscan2
- DICER1 | c.2432C>A p.P811H | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58629334; called by muse, varscan2
- DIDO1 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs779511231, COSV56629053; called by muse, mutect2, varscan2
- DIO3 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.072); catalogued as rs1197950208, COSV63774686, COSV63774743; called by muse, mutect2
- DIRAS2 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV65370865; called by muse, mutect2, varscan2
- DIS3L2 | c.1780G>T p.A594S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56065113; called by muse, mutect2, varscan2
- DISP3 | c.3359C>T p.S1120F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1387445881, COSV53838881; called by muse, mutect2, varscan2
- DLG3 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52087925; called by muse, mutect2, varscan2
- DLG5 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.96); PolyPhen benign (0.033); catalogued as rs1391008248, COSV64947957; called by muse, varscan2
- DLGAP3 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 33/80 reads (41%) | catalogued as COSV52398586; called by muse, mutect2, varscan2
- DLGAP4 | c.2827G>A p.D943N (on ENST00000339266 / NM_001365621.1; = p.D940N on NM_014902.6) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs114982034, COSV59424248; called by muse, mutect2, varscan2
- DLL1 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 11/196 reads (6%) | catalogued as COSV64538959; called by muse, mutect2
- DMAP1 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs762372274, COSV60000516; called by muse, mutect2, varscan2
- DMBT1 | c.1526T>C p.V509A | Missense Mutation (SNP) | VAF 184/745 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV57565757; called by muse, mutect2, varscan2
- DMD | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs765584669, COSV55866292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMPK | c.1627_1633del p.A543Ifs*6 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs1470320084; called by mutect2, pindel, varscan2
- DNAH10 | c.12416G>A p.G4139D (on ENST00000409039; = p.G4078D on NM_207437.3) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV69003658; called by muse, mutect2, varscan2
- DNAH17 | c.2678A>G p.E893G | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV101102404; called by muse, mutect2, varscan2
- DNAH7 | c.2009A>T p.H670L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.847); catalogued as COSV56789785; called by muse, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAI2 | c.1396C>G p.L466V | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV56758780, COSV56762943; called by muse, mutect2, varscan2
- DNAJA3 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs761966774, COSV52164677; called by muse, mutect2, varscan2
- DNAJB11 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as rs1462006657, COSV54002755; called by muse, mutect2, varscan2
- DNAJB5 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs1447856566, COSV56627644; called by muse, mutect2, varscan2
- DNASE1L1 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as COSV50011396; called by muse, mutect2, varscan2
- DOCK2 | c.2749C>T p.R917W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs1046162059, COSV56992193; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 26/66 reads (39%) | catalogued as rs782552436; called by pindel, varscan2
- DOCK6 | c.4097G>A p.R1366H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.302); catalogued as rs192428488; called by muse, mutect2, varscan2
- DOCK6 | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.54); catalogued as COSV52949825; called by muse, mutect2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs748134881; called by mutect2, varscan2
- DOCK8 | c.4067A>C p.K1356T | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV66619535; called by muse, mutect2, varscan2
- DPYSL5 | c.163G>T p.G55* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as COSV56516923; called by muse, mutect2, varscan2
- DSCAML1 | c.4811C>T p.A1604V (on ENST00000321322; = p.A1544V on NM_020693.4) | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58404209; called by muse, mutect2, varscan2
- DSP | c.8278G>A p.A2760T | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs991726607, COSV60940984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTWD1 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766234751, COSV52073316; called by muse, mutect2, varscan2
- DUOX1 | c.3379G>A p.V1127M | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1355150599, COSV58487027, COSV99075972; called by muse, mutect2, varscan2
- DYNC1H1 | c.2770C>T p.Q924* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV64143654; called by muse, varscan2
- DYNC1H1 | c.8929C>T p.R2977W | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64143659; called by muse, mutect2
- DYRK2 | c.235C>T p.H79Y (on ENST00000344096 / NM_006482.3; = p.H6Y on NM_003583.4) | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.027); catalogued as COSV59847684; called by muse, mutect2, varscan2
- ECEL1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs767625283, COSV58814522; called by muse, mutect2, varscan2
- ECM2 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs763096769, COSV60742206; called by muse, mutect2, varscan2
- ECRG4 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs770333533, COSV53000861; called by muse, mutect2, varscan2
- EEF1B2 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99260978, COSV99261454; called by muse, mutect2, varscan2
- EEF1D | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); catalogued as COSV52789266; called by muse, mutect2, varscan2
- EEF2 | c.2416G>A p.G806S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100500568, COSV58578496; called by muse, mutect2, varscan2
- EEPD1 | c.14T>C p.L5P | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54203750; called by muse, mutect2, varscan2
- EGF | c.2567A>G p.Q856R | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs745691794, COSV54485603; called by muse, mutect2, varscan2
- EHBP1L1 | c.1418A>G p.E473G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV58575421; called by muse, mutect2, varscan2
- EHMT1 | c.2128G>A p.G710S | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs398124403, COSV58382704; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- EIF2B3 | c.899G>A p.C300Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64518978; called by muse, mutect2, varscan2
- ELF3 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62840664; called by muse, mutect2, varscan2
- ELFN2 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68744751; called by muse, mutect2, varscan2
- EMC1 | c.2498T>C p.V833A | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs764903161, COSV64346777; called by muse, mutect2, varscan2
- EML2 | c.1145G>A p.G382D | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55604703; called by muse, mutect2, varscan2
- ENGASE | c.681dup p.R228Sfs*3 | Frame Shift Ins (INS) | VAF 18/82 reads (22%) | catalogued as rs1351589523; called by mutect2, pindel, varscan2
- ENPP3 | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 34/117 reads (29%) | catalogued as rs768656602, COSV62955523; called by muse, mutect2, varscan2
- ENTPD5 | c.1043del p.G348Vfs*3 | Frame Shift Del (DEL) | VAF 45/141 reads (32%) | catalogued as COSV58224109; called by mutect2, pindel, varscan2
- EPB41L1 | c.146C>A p.P49Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as COSV52445995; called by muse, mutect2, varscan2
- EPHA2 | c.563del p.C188Lfs*205 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | catalogued as COSV64453674; called by mutect2, pindel, varscan2
- EPN2 | c.1408del p.T470Qfs*5 | Frame Shift Del (DEL) | VAF 27/63 reads (43%) | catalogued as rs756461692; called by mutect2, varscan2
- EPX | c.704T>C p.L235P | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs967878818, COSV56599684; called by muse, mutect2, varscan2
- ERBB4 | c.2461C>A p.L821I | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61527834; called by muse, mutect2, varscan2
- ERGIC3 | c.879G>T p.E293D | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV53415660; called by muse, mutect2, varscan2
- ETFBKMT | c.346G>T p.G116* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV63189746; called by muse, mutect2, varscan2
- EVC2 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); catalogued as rs373953980; called by muse, mutect2, varscan2
- EWSR1 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs768226495, COSV58428364; called by muse, mutect2, varscan2
- EYA1 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV58175217; called by muse, mutect2, varscan2
- F13A1 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs767046666, COSV53553269, COSV99344063; called by muse, mutect2, varscan2
- F2 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV61317976; called by muse, mutect2, varscan2
- F8 | c.3870dup p.G1291Rfs*29 | Frame Shift Ins (INS) | VAF 22/90 reads (24%) | catalogued as rs1426645898; called by mutect2, varscan2
- F9 | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs1383972991, COSV54382719; called by muse, mutect2
- FAM118A | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV53419821; called by muse, mutect2
- FAM124A | c.253C>T p.R85W (on ENST00000322475 / NM_001242312.2; = p.R121W on NM_145019.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54478312; called by muse, mutect2
- FAM135B | c.2486T>G p.L829R | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.221); catalogued as COSV52756782; called by muse, mutect2
- FAM186B | c.2030G>A p.S677N | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV57724259; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 39/96 reads (41%) | catalogued as rs768952789; called by mutect2, pindel, varscan2
- FAN1 | c.2057C>T p.A686V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62952372; called by muse, mutect2, varscan2
- FAR2 | c.529del p.I177Sfs*8 | Frame Shift Del (DEL) | VAF 56/135 reads (41%) | catalogued as rs757443519; called by mutect2, varscan2
- FASN | c.2305-1G>T p.X769_splice | Splice Site (SNP) | VAF 6/52 reads (12%) | catalogued as COSV60759913; called by muse, mutect2, varscan2
- FASTKD1 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV70007350; called by muse, mutect2, varscan2
- FASTKD5 | c.2000dup p.F668Lfs*8 | Frame Shift Ins (INS) | VAF 28/91 reads (31%) | catalogued as rs1233549844; called by mutect2, pindel, varscan2
- FAT1 | c.734T>C p.V245A | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV71676240; called by muse, mutect2
- FBN3 | c.6251A>G p.D2084G | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54474673; called by muse, mutect2
- FBXL18 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV66669040; called by muse, mutect2
- FBXL18 | c.830G>C p.G277A | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.337); catalogued as COSV66669055; called by muse, mutect2
- FBXL5 | c.1100A>T p.D367V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV58014273; called by muse, mutect2, varscan2
- FBXL6 | c.1297T>C p.F433L | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs553722359, COSV57350890, COSV57353790; called by muse, mutect2
- FBXO32 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1159404147, COSV54890561; called by muse, mutect2, varscan2
- FBXO38 | c.3473G>A p.R1158H (on ENST00000340253 / NM_205836.3; = p.R1083H on NM_030793.5) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs754331887, COSV57031874; called by muse, mutect2, varscan2
- FBXO5 | c.818+1G>T p.X273_splice | Splice Site (SNP) | VAF 13/64 reads (20%) | catalogued as COSV57671764; called by muse, mutect2, varscan2
- FCGBP | c.10888G>A p.A3630T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs762789511; called by muse, mutect2, varscan2
- FDXR | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs1398360473, COSV53125693; called by muse, mutect2, varscan2
- FEM1C | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57231384, COSV57233062; called by muse, mutect2, varscan2
- FER | c.1613T>C p.I538T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55295011; called by muse, mutect2, varscan2
- FKRP | c.1429G>A p.V477I | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs1424035060, COSV59360182; called by muse, mutect2
- FLNB | c.7031C>A p.A2344D | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV55898390; called by muse, mutect2, varscan2
- FMN2 | c.1351C>A p.L451M | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV60457256; called by muse, mutect2
- FMN2 | c.1697T>C p.I566T | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV60457458; called by muse, mutect2
- FNTB | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 60/131 reads (46%) | catalogued as COSV55764663; called by muse, mutect2, varscan2
- FOSL2 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53105960; called by muse, mutect2, varscan2
- FOXB1 | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68526547; called by muse, mutect2, varscan2
- FOXD1 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61076863, COSV61076938; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 29/83 reads (35%) | catalogued as rs760347049; called by mutect2, pindel, varscan2
- FOXP1 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs1323763108, COSV59534753; called by muse, mutect2, varscan2
- FOXR2 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59259923; called by muse, mutect2, varscan2
- FRMPD4 | c.3212G>A p.R1071Q | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as rs1460455129, COSV66213484; called by muse, mutect2, varscan2
- FRYL | c.3232A>G p.S1078G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as COSV51964099; called by muse, mutect2, varscan2
- FTMT | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1321899820, COSV100360292, COSV58419974; called by muse, mutect2, varscan2
- FXR2 | c.1694A>G p.E565G | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV51469742; called by muse, mutect2, varscan2
- GABBR1 | c.1783G>A p.V595I | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs767518606, COSV63544851; called by muse, mutect2, varscan2
- GABRA1 | c.819G>A p.W273* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | catalogued as COSV50116243, COSV50122429; called by muse, mutect2, varscan2
- GABRA3 | c.901A>T p.R301* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV64806213; called by muse, mutect2, varscan2
- GAL3ST1 | c.802T>C p.W268R | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58893782; called by muse, mutect2, varscan2
- GARNL3 | c.2786A>C p.K929T | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV59231164; called by muse, mutect2, varscan2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | catalogued as rs548474277; called by mutect2, varscan2
- GBP4 | c.894G>T p.E298D | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.072); catalogued as COSV63256299; called by muse, mutect2
- GCAT | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 89/228 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV50650513; called by muse, mutect2, varscan2
- GCH1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54304046; called by muse, mutect2, varscan2
- GCLC | c.1651G>A p.V551M (on ENST00000643939; = p.V549M on NM_001498.4) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV57598146; called by muse, mutect2, varscan2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | catalogued as rs768450027; called by mutect2, varscan2
- GDPD3 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53777266; called by muse, mutect2
- GFUS | c.113G>A p.W38* | Nonsense Mutation (SNP) | VAF 45/228 reads (20%) | catalogued as COSV71254376; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs763147690; called by mutect2, varscan2
- GIMAP8 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.224); catalogued as rs1423611628, COSV56230049; called by muse, mutect2, varscan2
- GLB1 | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.859); catalogued as rs754538192, COSV56563660; called by muse, mutect2, varscan2
- GLO1 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV64905750; called by muse, mutect2, varscan2
- GMIP | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs533197570, COSV52291907; called by muse, mutect2, varscan2
- GML | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV55278815; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 22/93 reads (24%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GNL1 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV64835600; called by muse, mutect2
- GOLGB1 | c.9162+2T>C p.X3054_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as COSV61471967; called by muse, mutect2, varscan2
- GPC2 | c.989A>G p.Y330C | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.649); catalogued as COSV52786783; called by muse, mutect2, varscan2
- GPLD1 | c.2221dup p.L741Pfs*22 | Frame Shift Ins (INS) | VAF 11/61 reads (18%) | catalogued as rs749977099; called by mutect2, pindel, varscan2
- GPR12 | c.461T>C p.V154A | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV67345000; called by muse, mutect2, varscan2
- GPR45 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as rs200821166; called by muse, mutect2, varscan2
- GPRASP1 | c.3623C>T p.P1208L | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64355208; called by muse, mutect2
- GPX3 | c.579A>G p.I193M | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV59310658; called by muse, mutect2, varscan2
- GRIA2 | c.470-1G>T p.X157_splice | Splice Site (SNP) | VAF 20/47 reads (43%) | catalogued as COSV52386790; called by muse, mutect2, varscan2
- GRIN1 | c.1286A>G p.D429G | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.063); catalogued as COSV59301400; called by muse, mutect2, varscan2
- GRIN2A | c.3677G>A p.G1226D | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58058639; called by muse, mutect2, varscan2
- GRIN2A | c.2451G>T p.M817I | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58058647; called by muse, mutect2, varscan2
- GRM5 | c.2842G>A p.V948I (on ENST00000305447 / NM_001143831.2; = p.V916I on NM_000842.4) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs763053784, COSV59632919; called by muse, mutect2, varscan2
- GSK3B | c.1189G>A p.A397T (on ENST00000264235 / NM_001146156.2; = p.A410T on NM_002093.4) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.162); catalogued as COSV51784049; called by muse, mutect2, varscan2
- GSTCD | c.1398T>A p.C466* (on ENST00000360505 / NM_001031720.3; = p.C379* on NM_024751.3) | Nonsense Mutation (SNP) | VAF 44/116 reads (38%) | catalogued as COSV64735972; called by muse, mutect2, varscan2
- GTF2B | c.292A>G p.N98D | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.035); catalogued as rs906155833, COSV65137732; called by muse, mutect2, varscan2
- GTF2IRD2 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1422871321; called by muse, mutect2
- GUCY1B1 | c.936C>A p.Y312* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV52379573; called by mutect2, varscan2
- GZMH | c.612dup p.P205Afs*5 | Frame Shift Ins (INS) | VAF 23/129 reads (18%) | catalogued as rs770777921; called by mutect2, pindel, varscan2
- H1-5 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1230497255, COSV58901693; called by muse, mutect2
- HASPIN | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV54000788; called by muse, mutect2, varscan2
- HAUS3 | c.1285C>A p.P429T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV71319316; called by muse, mutect2, varscan2
- HAUS3 | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV71319317; called by muse, mutect2, varscan2
- HCCS | c.194A>C p.E65A | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV58239831; called by muse, mutect2, varscan2
- HCFC2 | c.1231+2T>C p.X411_splice | Splice Site (SNP) | VAF 25/47 reads (53%) | catalogued as COSV57560656; called by muse, mutect2, varscan2
- HDAC4 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs745919731, COSV61878138; called by muse, mutect2, varscan2
- HDGFL3 | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.681); catalogued as COSV55209010; called by muse, mutect2, varscan2
- HELZ | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV62381297; called by muse, mutect2, varscan2
- HERC1 | c.14123G>A p.W4708* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV71250596; called by muse, mutect2, varscan2
- HERC6 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as rs202101437, COSV52035379; called by muse, mutect2, varscan2
- HFM1 | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as rs769258836, COSV54035444; called by muse, mutect2, varscan2
- HGSNAT | c.560T>C p.L187S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV65535965; called by muse, mutect2, varscan2
- HHIP | c.1622G>T p.G541V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.786); catalogued as rs199900341, COSV56841452, COSV56844761; called by muse, mutect2, varscan2
- HJV | c.1208T>C p.V403A (on ENST00000336751 / NM_213653.4; = p.V290A on NM_145277.5) | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV60953363; called by muse, mutect2
- HMGXB4 | c.122del p.L41* | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as COSV99330175; called by mutect2, pindel, varscan2
- HMGXB4 | c.1172del p.K391Rfs*33 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs769388508; called by mutect2, varscan2
- HNRNPL | c.812C>T p.T271I | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV55495817; called by muse, mutect2, varscan2
- HOXB2 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs765776487, COSV57488442; called by muse, mutect2, varscan2
- HOXC10 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.028); catalogued as COSV57727268; called by muse, mutect2
- HOXC5 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV54538388; called by muse, mutect2, varscan2
- HOXD4 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as rs1241972255, COSV60461068, COSV60461118; called by muse, mutect2, varscan2
- HOXD8 | c.329del p.P110Lfs*67 | Frame Shift Del (DEL) | VAF 42/114 reads (37%) | catalogued as rs770632206; called by mutect2, pindel
- HS3ST2 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV54466161; called by muse, mutect2, varscan2
- HSD3B7 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs1417177954, COSV52682385; called by muse, mutect2, varscan2
- HSPA2 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV55970677; called by muse, mutect2, varscan2
- HSPG2 | c.6934C>T p.R2312W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs139721678; called by muse, mutect2, varscan2
- ICAM4 | c.38dup p.L13Ffs*17 | Frame Shift Ins (INS) | VAF 13/23 reads (57%) | catalogued as rs753968171; called by mutect2, varscan2
- ICMT | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV59474737; called by muse, mutect2, varscan2
- IDH2 | c.435dup p.T146Dfs*126 | Frame Shift Ins (INS) | VAF 18/94 reads (19%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, varscan2
- IFIT5 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs575185602, COSV65655805; called by muse, mutect2, varscan2
- IFNW1 | c.125A>G p.H42R | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV66522526; called by muse, mutect2, varscan2
- IFRD2 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1409998646, COSV57114867; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 63/201 reads (31%) | catalogued as rs760021495; called by mutect2, varscan2
- IGSF3 | c.2528G>A p.R843H (on ENST00000369486 / NM_001007237.3; = p.R863H on NM_001542.4) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs1322775814, COSV59597866; called by muse, mutect2, varscan2
- IKZF3 | c.530A>G p.H177R | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as COSV53107868; called by muse, mutect2
- IL1R2 | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 95/237 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358309794, COSV60209885; called by muse, mutect2, varscan2
- IL25 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs145694193; called by muse, mutect2, varscan2
- ILK | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs869025437, COSV54992886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INHBA | c.802del p.E268Kfs*91 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as COSV54219689, COSV54219996; called by mutect2, pindel, varscan2
- INPPL1 | c.3431C>T p.A1144V | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs778488376, COSV53359816; called by muse, mutect2, varscan2
- IQCN | c.1826G>A p.G609D | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV66578662; called by muse, mutect2
- IQSEC1 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs375728760; called by muse, mutect2, varscan2
- IQSEC3 | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as COSV100407235; called by muse, mutect2, varscan2
- IRF4 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.476); catalogued as rs375133421; called by muse, mutect2, varscan2
- IRF8 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 60/92 reads (65%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as rs375352812; called by muse, mutect2, varscan2
- IRS1 | c.1192A>G p.S398G | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV59340779; called by muse, mutect2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 86/274 reads (31%) | catalogued as rs780982673; called by mutect2, varscan2
- IRX1 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57362870; called by muse, mutect2, varscan2
- ITGA4 | c.346A>G p.K116E | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV52002719, COSV52004840; called by muse, mutect2, varscan2
- ITGA7 | c.1190del p.G397Vfs*7 (on ENST00000555728; = p.G353Vfs*7 on NM_002206.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 39/167 reads (23%) | catalogued as rs1361836055; called by mutect2, pindel, varscan2
- ITGAD | c.1234C>A p.L412M | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV66760596; called by muse, varscan2
- ITGAL | c.2474del p.P825Rfs*11 | Frame Shift Del (DEL) | VAF 75/228 reads (33%) | catalogued as COSV100776292; called by mutect2, pindel, varscan2
- ITGAV | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53719873; called by muse, mutect2, varscan2
- ITGB3 | c.1607G>A p.S536N | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV71385314; called by muse, mutect2
- ITGB4 | c.4337G>A p.R1446Q | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.719); catalogued as rs755867749, COSV52332777; called by muse, mutect2, varscan2
- ITGB6 | c.515T>C p.L172P | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1559237924, COSV104392993, COSV51799213; called by muse, mutect2, varscan2
- ITLN2 | c.892T>C p.F298L | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV63538334; called by muse, mutect2, varscan2
- ITPKB | c.1721T>C p.M574T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV55270841; called by muse, mutect2, varscan2
- ITPR1 | c.1799A>G p.H600R (on ENST00000354582; = p.H585R on NM_002222.7) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57006819; called by muse, mutect2, varscan2
- ITPR3 | c.7778T>C p.M2593T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100952004; called by muse, mutect2, varscan2
- JADE2 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs764787551, COSV50912760; called by muse, mutect2, varscan2
- JAG2 | c.2522C>T p.T841M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757271289, COSV59306884; called by mutect2, varscan2
- JPH2 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65905944; called by muse, mutect2, varscan2
- JSRP1 | c.250A>C p.K84Q | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV55560901; called by muse, mutect2, varscan2
- JUNB | c.623A>G p.Y208C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV56878976; called by muse, mutect2, varscan2
- KANSL3 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.185); catalogued as COSV62624176; called by muse, mutect2
- KATNA1 | c.281A>G p.E94G | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs918303162, COSV59504188; called by muse, mutect2, varscan2
- KATNIP | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.964); catalogued as COSV55193225; called by muse, mutect2, varscan2
- KCNA1 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1207573200, COSV66837998, COSV66838322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNA1 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as COSV66836958; called by muse, mutect2, varscan2
- KCNAB1 | c.1043C>T p.A348V (on ENST00000490337 / NM_172160.3; = p.A337V on NM_003471.3) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs1465626441, COSV56754904; called by muse, mutect2, varscan2
- KCNC1 | c.1303A>G p.I435V | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56399090; called by muse, mutect2, varscan2
- KCNC2 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.977); catalogued as rs1484667734, COSV54381551; called by muse, mutect2, varscan2
- KCNC4 | c.1075A>G p.K359E | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63925516; called by muse, mutect2, varscan2
- KCND2 | c.1490A>G p.Q497R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.012); catalogued as COSV58606860; called by muse, mutect2, varscan2
- KCNH1 | c.1717C>T p.R573C (on ENST00000271751 / NM_172362.3; = p.R546C on NM_002238.4) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55107502; called by muse, mutect2, varscan2
- KCNH7 | c.2044C>T p.R682* | Nonsense Mutation (SNP) | VAF 14/127 reads (11%) | catalogued as COSV59815575; called by muse, mutect2, varscan2
- KCNH8 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769502038, COSV60470269; called by muse, mutect2, varscan2
- KCNH8 | c.1285C>A p.L429M | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV60478858; called by muse, mutect2, varscan2
- KCNH8 | c.1976A>G p.H659R | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV60478870; called by muse, mutect2, varscan2
- KCNH8 | c.2352del p.N785Tfs*10 | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | catalogued as rs760381227; called by mutect2, pindel, varscan2
- KCNK10 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.398); catalogued as COSV56641288; called by muse, mutect2, varscan2
- KCNN2 | c.28G>A p.V10I (on ENST00000264773; = p.V222I on NM_021614.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.136); catalogued as COSV53300481; called by muse, mutect2, varscan2
- KCNS1 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV60261285; called by muse, mutect2, varscan2
- KCNS3 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as rs780182339, COSV58406456; called by muse, mutect2, varscan2
- KCNV1 | c.685C>A p.L229M | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52089491; called by muse, mutect2, varscan2
- KDELR3 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99318214; called by muse, mutect2
- KDM2B | c.3311G>A p.R1104H | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs782674526, COSV65645797; called by muse, varscan2
- KDM4C | c.2555A>G p.D852G | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67193989; called by muse, mutect2
- KDM4D | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58636848; called by muse, mutect2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 48/122 reads (39%) | catalogued as rs771545848; called by mutect2, varscan2
- KIAA1217 | c.2491G>A p.A831T | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.997); catalogued as rs149633076; called by mutect2, varscan2
- KIAA1549L | c.1882+2T>C p.X628_splice (on ENST00000321505; = p.X925_splice on NM_012194.3) | Splice Site (SNP) | VAF 37/101 reads (37%) | catalogued as rs779099273, COSV55772431; called by muse, mutect2, varscan2
- KIF13A | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.053); catalogued as rs776913211, COSV52467602; called by muse, mutect2, varscan2
- KIF1A | c.3602G>A p.R1201H | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs376697478; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF3C | c.2015G>A p.S672N | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs765711451, COSV53102469; called by muse, mutect2, varscan2
- KIF5B | c.431A>G p.D144G | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56656707; called by muse, mutect2, varscan2
- KIFC2 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770833900, COSV56763208; called by muse, mutect2, varscan2
- KIFC3 | c.1322G>T p.R441L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs782656825, COSV65553422; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KLC4 | c.1408C>A p.L470M | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52439684; called by muse, mutect2
- KLHL1 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773757751, COSV64780571; called by muse, mutect2, varscan2
- KLHL22 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as rs758974070, COSV61022455; called by muse, mutect2, varscan2
- KLHL41 | c.1296dup p.L433Tfs*9 | Frame Shift Ins (INS) | VAF 18/63 reads (29%) | catalogued as rs1288106608; called by mutect2, varscan2
- KLHL9 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62921748; called by muse, mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2C | c.4787A>G p.D1596G | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as COSV51510240; called by muse, mutect2, varscan2
- KMT2D | c.12175G>A p.A4059T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV56492448; called by muse, mutect2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 56/138 reads (41%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KPNB1 | c.296T>C p.L99S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51601064; called by muse, mutect2, varscan2
- KREMEN2 | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53557641; called by muse, mutect2, varscan2
- KRT34 | c.879C>A p.T293= | Splice Region (SNP) | VAF 41/148 reads (28%) | catalogued as COSV67450771; called by muse, mutect2, varscan2
- KRTAP10-12 | c.281G>A p.C94Y | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs782258353, COSV59982276; called by muse, mutect2
- KRTAP20-1 | c.37T>C p.Y13H | Missense Mutation (SNP) | VAF 19/84 reads (23%) | PolyPhen possibly damaging (0.876); catalogued as COSV58169045; called by muse, mutect2, varscan2
- KRTAP21-2 | c.99C>A p.Y33* | Nonsense Mutation (SNP) | VAF 32/92 reads (35%) | catalogued as COSV61684262, COSV61684736; called by muse, mutect2, varscan2
- KRTAP24-1 | c.469T>G p.C157G | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.196); catalogued as COSV61089531; called by muse, mutect2
- KRTAP26-1 | c.413G>A p.C138Y | Missense Mutation (SNP) | VAF 99/258 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV62129447; called by muse, mutect2, varscan2
- KRTAP5-5 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 77/163 reads (47%) | PolyPhen benign (0.055); catalogued as rs745406927, COSV68785977; called by muse, mutect2, varscan2
- LAMB2 | c.4840G>A p.A1614T | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV59738469; called by muse, mutect2, varscan2
- LARGE1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.255); catalogued as COSV61673520; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LARS2 | c.*682G>A | Splice Region (SNP) | VAF 23/56 reads (41%) | catalogued as rs773002979, COSV55532746; called by muse, mutect2, varscan2
- LBR | c.1496T>C p.V499A | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV55292245; called by muse, mutect2, varscan2
- LETMD1 | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs1417803419, COSV50400507; called by muse, mutect2
- LEXM | c.475A>G p.T159A | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV64024426; called by muse, mutect2, varscan2
- LGALS9C | c.187A>G p.N63D | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60196824; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs775423572; called by mutect2, pindel, varscan2
- LIG1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as rs368320718; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | catalogued as rs780042765; called by mutect2, varscan2
- LLGL2 | c.2218G>T p.G740C | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51417894; called by muse, mutect2
- LMO7 | c.4789C>T p.R1597C (on ENST00000357063; = p.R1278C on NM_005358.5) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58539910; called by muse, mutect2, varscan2
- LONP1 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377243139; called by muse, mutect2, varscan2
- LRP10 | c.1337T>C p.V446A | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV62079011; called by muse, mutect2, varscan2
- LRP12 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as COSV52626965; called by muse, mutect2, varscan2
- LRRC41 | c.1937T>C p.L646P | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58442695; called by muse, mutect2, varscan2
- LRRC49 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs1208450042, COSV53007931; called by muse, mutect2
- LRWD1 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.157); catalogued as COSV52962446; called by muse, mutect2, varscan2
- LSM14A | c.1288A>G p.T430A | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV70885770; called by muse, mutect2, varscan2
- LTBP1 | c.1937G>A p.G646D (on ENST00000404816 / NM_206943.4; = p.G320D on NM_000627.4) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63198875; called by muse, mutect2
- LVRN | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs142239251, COSV63496163; called by muse, mutect2, varscan2
- LY86 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs1260950510, COSV57914200; called by muse, mutect2, varscan2
- LYPD6 | c.40A>C p.S14R | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.503); catalogued as COSV61942656; called by muse, mutect2, varscan2
- MAB21L1 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV59827889; called by muse, mutect2
- MAFB | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV64827208; called by muse, mutect2
- MAGI1 | c.3895C>T p.R1299W | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58332508; called by muse, mutect2
- MAGI2 | c.2920C>T p.R974W | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751815413, COSV62646634, COSV62702980; called by muse, mutect2, varscan2
- MAP3K21 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); catalogued as rs1435730142, COSV64041723; called by muse, mutect2
- MAP4K2 | c.1001A>C p.Q334P | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.795); catalogued as COSV53649348; called by muse, mutect2, varscan2
- MAPK13 | c.149A>C p.K50T | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV52985431; called by muse, mutect2
- MAU2 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV53238576; called by muse, mutect2, varscan2
- MAZ | c.70del p.V24Wfs*5 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs1484448771; called by mutect2, pindel, varscan2
- MBD2 | c.471del p.G158Dfs*7 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs755716804, COSV56502366; called by mutect2, pindel, varscan2
- MBOAT2 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs756373257, COSV60007885; called by muse, mutect2, varscan2
- MCEE | c.419del p.K140Rfs*6 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs776473131; called by mutect2, varscan2
- MCF2L2 | c.2638G>T p.V880L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61062658; called by muse, mutect2, varscan2
- MCM4 | c.2363C>T p.T788M | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs781271560, COSV50634144; called by muse, mutect2, varscan2
- MCM6 | c.1528T>C p.Y510H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51469823; called by muse, mutect2, varscan2
- MCTP1 | c.1279G>A p.G427S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs145487587; called by muse, mutect2, varscan2
- MDC1 | c.5914G>A p.D1972N | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1371318631, COSV64525278; called by muse, mutect2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MECOM | c.473G>A p.R158Q (on ENST00000468789 / NM_001105078.4; = p.R346Q on NM_004991.4) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1162779068, COSV52968047; called by muse, mutect2, varscan2
- MED13L | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 76/92 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs139163900, COSV56120587; called by muse, mutect2, varscan2
- MED25 | c.957dup p.F320Lfs*79 | Frame Shift Ins (INS) | VAF 9/76 reads (12%) | catalogued as rs1442933539; called by mutect2, pindel, varscan2
- MEP1A | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.065); catalogued as rs200226039, COSV57922872; called by muse, mutect2, varscan2
- METTL14 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as rs749542576, COSV66311409; called by muse, mutect2, varscan2
- METTL27 | c.122A>G p.Q41R | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs1554636539, COSV52897395; called by muse, mutect2, varscan2
- MFSD13A | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 87/191 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53269617; called by muse, mutect2, varscan2
- MFSD14B | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745326058, COSV64700669; called by muse, mutect2, varscan2
- MFSD6L | c.1142T>C p.I381T | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV61003753, COSV61006414; called by muse, mutect2, varscan2
- MGAT4C | c.1174del p.I392Lfs*3 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs746398787; called by mutect2, varscan2
- MGAT4C | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771884299, COSV59838642; called by muse, varscan2
- MIA3 | c.2681C>G p.S894C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); catalogued as COSV100719313, COSV60518751; called by muse, mutect2, varscan2
- MIB2 | c.2518del p.D840Tfs*22 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs747046371; called by mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIP | c.204T>G p.N68K | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57789023; called by muse, mutect2, varscan2
- MKNK2 | c.1110+1G>A p.X370_splice | Splice Site (SNP) | VAF 44/109 reads (40%) | catalogued as COSV51735303; called by muse, mutect2, varscan2
- MMP14 | c.848A>G p.Y283C | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61289802; called by muse, mutect2
- MMP16 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs141858403; called by muse, mutect2, varscan2
- MMP25 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757540476, COSV60679837; called by muse, mutect2, varscan2
- MMP9 | c.1394del p.P465Rfs*45 | Frame Shift Del (DEL) | VAF 51/166 reads (31%) | catalogued as rs1344630709, COSV63434235, COSV63434495; called by mutect2, pindel, varscan2
- MMRN1 | c.705A>C p.K235N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV53343420; called by muse, mutect2, varscan2
- MMS22L | c.2799del p.V934Ffs*8 | Frame Shift Del (DEL) | VAF 21/68 reads (31%) | catalogued as rs1562416103; called by mutect2, pindel, varscan2
- MOCS1 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs774298259, COSV51421329; called by muse, mutect2, varscan2
- MOS | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as COSV61337043; called by muse, mutect2, varscan2
- MOSPD3 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.149); catalogued as COSV56159032; called by muse, mutect2, varscan2
- MPDZ | c.4318G>A p.A1440T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs750164135, COSV59925464; called by mutect2, varscan2
- MPDZ | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs759687715, COSV59954921; called by muse, mutect2, varscan2
- MROH8 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.652); catalogued as COSV54120437, COSV54125897; called by muse, mutect2, varscan2
- MSC | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); catalogued as COSV57697663; called by muse, mutect2, varscan2
- MT1B | c.137A>G p.Q46R | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.283); catalogued as rs1039926850, COSV57619733; called by muse, mutect2, varscan2
- MUC4 | c.13484A>G p.D4495G (on ENST00000463781 / NM_018406.7; = p.D259G on NM_004532.6) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV57805880; called by muse, mutect2, varscan2
- MUC5B | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as COSV71596304; called by muse, mutect2
- MUSK | c.2064G>T p.Q688H | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV51898488; called by muse, mutect2
- MYBL1 | c.1259dup p.N420Kfs*4 | Frame Shift Ins (INS) | VAF 30/153 reads (20%) | catalogued as rs1563531407; called by mutect2, varscan2
- MYCBP2 | c.9685G>A p.A3229T (on ENST00000357337; = p.A3267T on NM_015057.5) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV62041919; called by muse, mutect2, varscan2
- MYCBP2 | c.6838dup p.M2280Nfs*26 (on ENST00000357337; = p.M2318Nfs*26 on NM_015057.5) | Frame Shift Ins (INS) | VAF 22/95 reads (23%) | catalogued as rs776222254; called by mutect2, varscan2
- MYH11 | c.2599C>T p.R867W | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs745429737, COSV55550056; called by muse, mutect2, varscan2
- MYH4 | c.1589C>A p.P530H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55127526; called by muse, mutect2, varscan2
- MYO15A | c.8350G>T p.G2784C | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52767651; called by muse, mutect2, varscan2
- MYO18A | c.627del p.V210Wfs*86 | Frame Shift Del (DEL) | VAF 42/126 reads (33%) | catalogued as COSV62866672, COSV62872682; called by mutect2, pindel, varscan2
- MYOZ1 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs773215819, COSV63772711; called by muse, mutect2, varscan2
- NACC1 | c.926T>C p.M309T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV99457014; called by muse, mutect2, varscan2
- NALCN | c.3056dup p.L1019Ffs*30 | Frame Shift Ins (INS) | VAF 48/114 reads (42%) | catalogued as rs772394714; called by mutect2, varscan2
- NAV2 | c.3739G>T p.G1247C (on ENST00000396087 / NM_001244963.2; = p.G1224C on NM_145117.5) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV60666202; called by muse, mutect2, varscan2
- NAV3 | c.4723C>T p.R1575W | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770148138, COSV57063340, COSV57118643, COSV99888175; called by muse, mutect2, varscan2
- NBEA | c.2907G>T p.E969D | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.956); catalogued as COSV59827871; called by muse, mutect2
- NCKAP1 | c.1687T>C p.S563P | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.329); catalogued as COSV100719910, COSV62944156; called by muse, mutect2, varscan2
- NDRG1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs144310406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NDUFB11 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.072); catalogued as COSV52101786, COSV52102957; called by muse, mutect2, varscan2
- NDUFS4 | c.104T>C p.L35S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV99692140; called by muse, mutect2, varscan2
- NEB | c.9640G>A p.D3214N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs1319060772, COSV51451739; called by muse, mutect2, varscan2
- NEB | c.8435G>A p.R2812H | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs772240430, COSV51425086; called by muse, mutect2, varscan2
- NEO1 | c.1260A>T p.Q420H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56078962; called by muse, mutect2, varscan2
- NEO1 | c.3194-2A>G p.X1065_splice | Splice Site (SNP) | VAF 13/64 reads (20%) | catalogued as COSV56078971; called by muse, mutect2, varscan2
- NEXMIF | c.971A>G p.K324R | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV50168203, COSV99281502; called by muse, mutect2, varscan2
- NFIA | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs780521254, COSV64544777; called by muse, mutect2, varscan2
- NFKBIL1 | c.19dup p.Q7Pfs*84 | Frame Shift Ins (INS) | VAF 5/22 reads (23%) | catalogued as rs1376248551; called by mutect2, pindel, varscan2
- NIN | c.3421C>T p.R1141W | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs747335491, COSV55408822; called by muse, mutect2, varscan2
- NINL | c.2624C>G p.A875G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54006202, COSV54009857; called by muse, mutect2, varscan2
- NINL | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs762729377, COSV54009869; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | catalogued as rs145147241; called by mutect2, varscan2
- NIPAL3 | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 94/468 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV50238494; called by muse, varscan2
- NKPD1 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV58730500; called by muse, mutect2, varscan2
- NKX2-3 | c.605A>G p.K202R | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV60729395; called by muse, mutect2
- NLGN3 | c.989A>G p.Y330C (on ENST00000358741 / NM_181303.2; = p.Y310C on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV62445571; called by muse, mutect2, varscan2
- NLRC3 | c.2200G>A p.V734I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767543107, COSV57096542; called by muse, mutect2, varscan2
- NLRP14 | c.3255_3257del p.E1085del | In Frame Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs1331544899; called by pindel, varscan2
- NLRP3 | c.1034T>G p.L345R | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60231950; called by muse, mutect2, varscan2
- NLRP9 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.11); catalogued as COSV60468436; called by muse, mutect2
- NOC4L | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as rs201466638, COSV57960354; called by muse, mutect2, varscan2
- NOC4L | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs1264101046, COSV57960362; called by muse, varscan2
- NOS3 | c.1462A>G p.T488A | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV52496560; called by muse, mutect2, varscan2
- NOTCH3 | c.3646G>A p.A1216T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs1257835251, COSV54625575; called by muse, mutect2, varscan2
- NPEPL1 | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV61940835; called by muse, mutect2, varscan2
- NRAP | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs369577578, COSV63491817; called by muse, mutect2, varscan2
- NRAP | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs1341131885, COSV63490671; called by muse, mutect2
- NRM | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.374); catalogued as rs762747317, COSV51299620; called by muse, mutect2, varscan2
- NRXN3 | c.2840G>A p.R947H (on ENST00000335750 / NM_001330195.2; = p.R574H on NM_004796.6) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.584); catalogued as rs140528152; called by muse, mutect2, varscan2
- NTRK2 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV52885252; called by muse, mutect2, varscan2
- NUP210 | c.403del p.L135Wfs*3 | Frame Shift Del (DEL) | VAF 29/87 reads (33%) | catalogued as rs762804106; called by mutect2, pindel, varscan2
- OGDH | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs1246055947, COSV56058037; called by muse, mutect2, varscan2
- OGDHL | c.2517+2T>C p.X839_splice | Splice Site (SNP) | VAF 14/224 reads (6%) | catalogued as rs1257243912, COSV65105048; called by muse, mutect2
- OLFM1 | c.254G>A p.C85Y (on ENST00000371793 / NM_001282611.2; = p.C67Y on NM_006334.4) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52963909; called by muse, mutect2, varscan2
- OPRK1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1162961106, COSV55568576; called by muse, mutect2, varscan2
- OR2A5 | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV68739231; called by muse, mutect2
- OR52A1 | c.814del p.S272Pfs*36 | Frame Shift Del (DEL) | VAF 34/108 reads (31%) | catalogued as rs1342694715, COSV61092188; called by mutect2, pindel, varscan2
- OR52W1 | c.839T>A p.I280N | Missense Mutation (SNP) | VAF 30/469 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV60951887; called by muse, mutect2
- OR5B12 | c.597del p.F199Lfs*13 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | catalogued as rs747074822; called by mutect2, varscan2
- OR5I1 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV56889395; called by muse, mutect2, varscan2
- OR5M10 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73242466; called by muse, mutect2
- ORAI2 | c.617C>A p.P206H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV62689526, COSV62690659; called by muse, mutect2, varscan2
- OSBP | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751950026, COSV55666084; called by muse, varscan2
- OTOP2 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs760162062, COSV58880844; called by muse, mutect2, varscan2
- OTUD7B | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs1030113784, COSV64918019; called by muse, mutect2, varscan2
- OXGR1 | c.164T>C p.I55T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1214147279, COSV53658787; called by muse, mutect2, varscan2
- P3H3 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782398555, COSV51836821; called by muse, mutect2
- PABPC3 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs532491618, COSV55807003, COSV99879723; called by muse, mutect2, varscan2
- PALD1 | c.1573C>A p.L525M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV54973986; called by muse, mutect2, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 74/256 reads (29%) | catalogued as rs751755759; called by mutect2, varscan2
- PAN2 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57754103; called by muse, mutect2, varscan2
- PASK | c.3198+2T>C p.X1066_splice | Splice Site (SNP) | VAF 17/74 reads (23%) | catalogued as COSV52162046; called by muse, mutect2, varscan2
- PATZ1 | c.295G>C p.G99R | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.934); catalogued as COSV53231513, COSV99315713; called by muse, mutect2
- PAX1 | c.1066T>C p.S356P | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV68273630; called by muse, mutect2, varscan2
- PAX4 | c.812T>C p.L271P | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV58389150; called by muse, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PCDH17 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV64973154, COSV64976719; called by muse, mutect2, varscan2
- PCDH17 | c.2907C>A p.Y969* | Nonsense Mutation (SNP) | VAF 41/70 reads (59%) | catalogued as COSV64980210; called by muse, mutect2, varscan2
- PCDH7 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs1298790860; called by muse, mutect2
- PCDH8 | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1047810990, COSV58811189; called by muse, mutect2, varscan2
- PCDH8 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as COSV58815291; called by muse, mutect2, varscan2
- PCDH9 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 56/95 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60595456; called by muse, mutect2, varscan2
- PCDHA11 | c.1117G>A p.V373M | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs199741132, COSV56544889; called by muse, mutect2, varscan2
- PCDHA13 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as COSV56479903; called by muse, mutect2
- PCDHA5 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs782174780, COSV65354730; called by muse, mutect2, varscan2
- PCDHA5 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs1197473169, COSV65358797; called by muse, mutect2
- PCDHA8 | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 98/236 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782736515, COSV65334989, COSV65336971; called by muse, mutect2, varscan2
- PCDHB12 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV53397189, COSV53401737; called by muse, mutect2, varscan2
- PCDHB14 | c.1141A>C p.M381L | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as COSV53391664; called by muse, mutect2, varscan2
- PCDHB6 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV50739561; called by muse, mutect2, varscan2
- PCDHB8 | c.959T>C p.I320T | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV50825825; called by muse, mutect2
- PCDHGA3 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 95/239 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as COSV54013481; called by muse, mutect2, varscan2
- PCDHGA3 | c.2090T>C p.V697A | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.167); catalogued as rs775333525, COSV54046811; called by muse, varscan2
- PCDHGB5 | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53910417; called by muse, mutect2, varscan2
- PCMT1 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1165670020, COSV61191396; called by muse, mutect2, varscan2
- PCNT | c.5846G>T p.R1949M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV64033685; called by muse, mutect2
- PCTP | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52124009; called by muse, mutect2, varscan2
- PDIA5 | c.1157del p.P386Rfs*26 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | catalogued as rs766425459, COSV60251765; called by mutect2, varscan2
- PDPN | c.41C>T p.A14V (on ENST00000621990; = p.A90V on NM_006474.4) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.678); catalogued as COSV53848837; called by muse, mutect2, varscan2
- PDZRN3 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.104); catalogued as rs755503041, COSV55190111; called by muse, mutect2, varscan2
- PGF | c.505T>C p.C169R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99462523; called by muse, mutect2, varscan2
- PHF20 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 44/118 reads (37%) | catalogued as COSV59186928; called by muse, mutect2, varscan2
- PHF20L1 | c.1513A>G p.T505A | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV55199245; called by muse, mutect2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PI4KA | c.3392G>A p.C1131Y | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV55425155; called by muse, mutect2, varscan2
- PIAS2 | c.1841T>C p.I614T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV67095005; called by muse, mutect2, varscan2
- PIBF1 | c.33del p.V12* | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | catalogued as rs925772654; called by mutect2, pindel, varscan2
- PIK3R5 | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV52659274; called by muse, mutect2, varscan2
- PITX2 | c.425A>G p.K142R (on ENST00000354925 / NM_001204397.1; = p.K149R on NM_000325.6) | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as CD004093, COSV60742457; called by muse, mutect2, varscan2
- PIWIL2 | c.2539A>G p.M847V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as rs956557934, COSV63254401; called by muse, mutect2, varscan2
- PKD1 | c.3421G>A p.G1141S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as rs753385964, COSV51927122; called by muse, mutect2
- PKHD1L1 | c.8155G>T p.G2719W | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65755022; called by muse, mutect2, varscan2
- PKN1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54404761; called by muse, mutect2, varscan2
- PLA2G2A | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.882); catalogued as rs779263473, COSV64287706; called by muse, mutect2, varscan2
- PLAAT4 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 112/328 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs377604818; called by muse, varscan2
- PLCB4 | c.2161T>C p.Y721H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53820643; called by muse, mutect2, varscan2
- PLEC | c.10709T>C p.V3570A (on ENST00000322810 / NM_201380.4; = p.V3460A on NM_000445.5) | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.798); catalogued as COSV59608913, COSV59702511; called by muse, mutect2, varscan2
- PLEKHA1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs758093671, COSV64570480; called by muse, mutect2, varscan2
- PLEKHG3 | c.3259C>T p.R1087W (on ENST00000394691; = p.R1143W on NM_001308147.2) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368387962; called by muse, mutect2, varscan2
- PLEKHH1 | c.190G>T p.V64L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV61288278; called by muse, mutect2, varscan2
- PLIN5 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1466692340, COSV67851085; called by muse, mutect2, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs772701630; called by mutect2, varscan2
- PLOD2 | c.620C>A p.A207D | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV51469834; called by mutect2, varscan2
- PLOD3 | c.876del p.Q293Sfs*65 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | catalogued as rs746342377, COSV56183473; called by mutect2, varscan2
- PLPPR3 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100608408; called by muse, mutect2
- PLXNA3 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV63755996; called by muse, mutect2
- PLXNB3 | c.4099C>T p.R1367C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs782068600, COSV62797349; called by muse, mutect2, varscan2
- PLXND1 | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV60720033; called by muse, mutect2, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- PNISR | c.1491del p.E498Sfs*85 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | catalogued as rs1401239378; called by mutect2, pindel, varscan2
- POLR2I | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 58/168 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV52900846; called by muse, mutect2, varscan2
- POLR3E | c.865+2T>C p.X289_splice | Splice Site (SNP) | VAF 28/65 reads (43%) | catalogued as COSV55403956; called by muse, mutect2, varscan2
- POLR3E | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs760383677, COSV55402016; called by muse, mutect2, varscan2
- POLRMT | c.383A>C p.K128T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV73933736; called by muse, mutect2, varscan2
- POU3F4 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64541389; called by muse, mutect2, varscan2
- PPIE | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs758313497, COSV60971602; called by mutect2, varscan2
- PPIG | c.2042del p.K681Rfs*12 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs775130624; called by mutect2, pindel, varscan2
- PPP1R36 | c.135-2A>G p.X45_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as COSV53901898, COSV53904161; called by muse, mutect2, varscan2
- PPP2R1B | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782083920, COSV59534871; called by muse, mutect2, varscan2
- PPP2R5B | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs775390875, COSV51213390; called by muse, mutect2, varscan2
- PPP6R2 | c.1717G>A p.A573T (on ENST00000216061 / NM_001365836.1; = p.A546T on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53299471; called by muse, mutect2, varscan2
- PRAM1 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs757273249, COSV55317523; called by muse, mutect2, varscan2
- PRAMEF20 | c.399A>C p.K133N | Missense Mutation (SNP) | VAF 34/441 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.678); catalogued as rs1424873713; called by muse, mutect2
- PRDM13 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.185); catalogued as COSV65030791; called by muse, mutect2, varscan2
- PRDM7 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs371183401; called by muse, mutect2, varscan2
- PRG3 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 87/269 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs1192610856, COSV54663913; called by muse, mutect2, varscan2
- PRKACG | c.928_930del p.K310del | In Frame Del (DEL) | VAF 38/93 reads (41%) | catalogued as rs761115327; called by pindel, varscan2
- PRKD2 | c.1145T>C p.M382T | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV52190275; called by muse, mutect2, varscan2
- PRMT1 | c.1114T>C p.*372Rext*16 | Nonstop Mutation (SNP) | VAF 57/152 reads (38%) | catalogued as COSV54922739; called by muse, mutect2, varscan2
- PRMT7 | c.1074_1075del p.R358Sfs*9 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | catalogued as rs763953657; called by pindel, varscan2
- PRMT8 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV54216348, COSV54219942; called by muse, mutect2, varscan2
- PROX2 | c.695G>T p.R232M | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as COSV71520237; called by muse, mutect2, varscan2
- PRPF3 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as rs201882091, COSV61396614; called by muse, mutect2, varscan2
- PRR30 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs149337790; called by muse, mutect2, varscan2
- PRSS54 | c.1070A>G p.D357G | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54688136; called by muse, mutect2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PSG3 | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs776770877, COSV59507154; called by muse, mutect2, varscan2
- PSMD2 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs751393532, COSV59531629; called by muse, mutect2, varscan2
- PSMD6 | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55761564; called by muse, mutect2, varscan2
- PSORS1C1 | c.13+2T>C p.X5_splice | Splice Site (SNP) | VAF 6/62 reads (10%) | catalogued as rs746054783, COSV52550149; called by mutect2, varscan2
- PTCD1 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV52859627; called by muse, varscan2
- PTDSS1 | c.811A>C p.S271R | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV61266956; called by muse, mutect2
- PTDSS2 | c.455A>C p.Q152P | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as COSV57280218; called by muse, mutect2, varscan2
- PTH1R | c.951G>T p.E317D | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV57317281, COSV57318121; called by muse, mutect2, varscan2
- PTOV1 | c.1248dup p.*417Vfs*24 (on ENST00000391842; = p.*417Vfs*77 on NM_017432.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | catalogued as rs750392317; called by mutect2, varscan2
- PTPN13 | c.3778C>T p.Q1260* (on ENST00000411767 / NM_080683.3; = p.Q1241* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as COSV57418831; called by muse, mutect2, varscan2
- PTPN18 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs754021544, COSV99447809; called by muse, mutect2, varscan2
- PTPRA | c.478T>A p.S160T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); catalogued as COSV53789524; called by muse, mutect2, varscan2
- PTX3 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV99904882; called by muse, mutect2, varscan2
- PVRIG | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV52783012; called by muse, mutect2
- PXDC1 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV66662191; called by muse, mutect2, varscan2
- PYGB | c.1033C>A p.L345I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.062); catalogued as COSV53823546; called by muse, mutect2, varscan2
- PYGO1 | c.1117G>T p.G373* | Nonsense Mutation (SNP) | VAF 8/108 reads (7%) | catalogued as COSV57350569; called by muse, mutect2
- QRICH2 | c.2876G>A p.G959D | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV53158495; called by muse, mutect2, varscan2
945 further variants in this file (543 protein-altering or splice-affecting, 366 silent, 36 other) are not listed here.
